Gene-level copy-number profile of tumor specimen TCGA-A6-2684-01A from TCGA case TCGA-A6-2684, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 75.9 years (27,708 days).
Specimen TCGA-A6-2684-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.39c9616e-e666-4647-b041-43df4016859d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-2684-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (3 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/37ccbb71-36c7-4b10-bc49-973f185f6e2a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 7,684; copy number 2: 49,674; copy number 3: 2,422; copy number 4: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-2684-01A-01D-A274-01): tumor purity 0.63, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:33,013,087–34,174,964, 1 gene (within-gene range 0–1): ASIC2.
- chr17:33,529,787–34,482,148, 28 genes: AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,684. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
